Gene-level copy-number profile of tumor specimen TCGA-NC-A5HI-01A from TCGA case TCGA-NC-A5HI, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.4 years (24,981 days).
Specimen TCGA-NC-A5HI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.66145b48-c2a6-43da-a56f-2eeab2648b14.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3750b006-878d-493f-a434-cb2d8faeed90

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 18,491; copy number 2: 37,966; copy number 3: 1,905; copy number 4: 1,278; copy number 5: 72; copy number 7: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HI-01A-11D-A26L-01): tumor purity 0.6, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:37,693,655–37,861,802, 3 genes: ITGA9-AS1, RPL21P135, NDUFAF4P3.
- chr4:175,286,605–175,403,110, 2 genes: AC095050.2, AC095050.1.
- chr4:184,254,509–184,490,293, 10 genes: AC079080.1, RN7SL28P, MYL12BP2, LINC02363, LINC02362, IRF2, SNORD79, AC099343.2, IRF2-DT, AC099343.3.
- chr9:20,341,669–20,622,499, 1 gene (within-gene range 0–1): MLLT3.
- chr9:20,502,265–22,824,213, 63 genes (broad region; genes not listed).
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.
- chr10:62,682,652–63,521,850, 14 genes (within-gene range 0–1): AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 78 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:31,165,618–31,645,160, 6 genes, copy number 7: AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr14:21,990,496–22,506,702, 72 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,096. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
